Somatic mutation profile of tumor specimen TCGA-62-A471-01A (aliquot TCGA-62-A471-01A-12D-A24D-08) from TCGA case TCGA-62-A471, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 64.9 years (23,689 days).
Specimen TCGA-62-A471-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09a2b0ba-0978-48ff-aede-a989eafb7275.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-62-A471-10A (Blood Derived Normal), aliquot TCGA-62-A471-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab6c6851-eef1-409a-9de6-d566cbfd31a1

The open-access MAF lists 125 somatic variants for this specimen: 84 protein-altering or splice-affecting, 34 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 34, Nonsense Mutation 5, RNA 4, Splice Region 2, Frame Shift Del 2, 3'Flank 1, Intron 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520017, COSV58821219; ClinVar: likely pathogenic; called by mutect2, varscan2
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 33/72 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALDH2 | c.1281C>A p.F427L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99923323; called by muse, mutect2, varscan2
- ALKBH6 | c.110A>G p.Y37C (on ENST00000252984 / NM_001297701.2; = p.Y65C on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as COSV99431338; called by muse, mutect2, varscan2
- ARHGAP5 | c.3419G>A p.R1140K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.031); catalogued as COSV100565727, COSV100565739; called by muse, mutect2, varscan2
- BEST3 | c.1588G>C p.E530Q | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.073); catalogued as COSV100438075; called by muse, mutect2, varscan2
- C1GALT1 | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99777666; called by muse, mutect2, varscan2
- CACNA1D | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371212198; called by muse, mutect2, varscan2
- CAPSL | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV101274344; called by muse, mutect2, varscan2
- CCDC7 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99511625, COSV99512010; called by muse, mutect2
- CDADC1 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.831); catalogued as COSV99212618; called by muse, mutect2, varscan2
- CDH10 | c.689G>A p.R230K | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV52577328; called by muse, mutect2, varscan2
- CDHR2 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV99992246; called by muse, mutect2, varscan2
- CEACAM5 | c.1877C>G p.S626C | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99704191; called by muse, mutect2, varscan2
- CNTNAP5 | c.3179C>T p.S1060F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV70487089; called by muse, mutect2, varscan2
- COG5 | c.1588G>C p.G530R | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV51758497, COSV99773368; called by muse, varscan2
- CRY1 | c.1205G>T p.C402F | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV99151089; called by muse, mutect2, varscan2
- CSMD1 | c.1850C>T p.S617L (on ENST00000520002; = p.S616L on NM_033225.6) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as COSV100154411; called by muse, mutect2, varscan2
- DNM2 | c.847C>G p.Q283E | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV100118149; called by muse, mutect2, varscan2
- DOCK5 | c.3037C>T p.Q1013* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as COSV99378124; called by muse, mutect2, varscan2
- DOP1B | c.832C>T p.L278F | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs753156977, COSV101215871; called by muse, mutect2, varscan2
- DPPA3 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61502905; called by muse, mutect2, varscan2
- DROSHA | c.2879C>T p.S960L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs757002340, COSV100757870, COSV60782435; called by muse, mutect2, varscan2
- DTL | c.1378C>G p.L460V | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV100877294; called by muse, mutect2
- EFCAB5 | c.738G>C p.K246N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100300852, COSV57935305; called by muse, mutect2, varscan2
- EPHA3 | c.2494G>C p.D832H | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60699447, COSV60707218, COSV60708573; called by muse, mutect2, varscan2
- EPHA3 | c.2512G>A p.D838N | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.251); catalogued as COSV60713962; called by muse, mutect2, varscan2
- ERBB3 | c.3652G>A p.E1218K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as COSV99918016; called by muse, mutect2, varscan2
- FBN3 | c.5378G>T p.R1793L | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.165); catalogued as COSV54465166, COSV99561951; called by muse, mutect2, varscan2
- FER1L6 | c.447C>A p.S149= | Splice Region (SNP) | VAF 39/86 reads (45%) | catalogued as COSV101206227; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1324C>G p.Q442E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as rs1220658629, COSV100438260; called by muse, mutect2, varscan2
- GAD1 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.267); catalogued as COSV100828036; called by muse, mutect2, varscan2
- GATA4 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100633070; called by muse, mutect2, varscan2
- GCNT2 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV101097683; called by muse, mutect2, varscan2
- GJA1 | c.917G>A p.S306N | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99247351; called by muse, mutect2, varscan2
- GPR152 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.846); catalogued as rs529951302, COSV100351693; called by muse, mutect2, varscan2
- GPR65 | c.946C>G p.Q316E | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99966173; called by muse, mutect2, varscan2
- GRHL2 | c.502A>T p.M168L | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV99307925; called by muse, mutect2, varscan2
- H2BC3 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV100778320, COSV63550856; called by muse, mutect2, varscan2
- HCAR3 | c.740G>C p.S247T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV100811830; called by muse, mutect2
- HSF5 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs371929044; called by muse, mutect2, varscan2
- IFT52 | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.658); catalogued as COSV100887683; called by muse, mutect2, varscan2
- IGSF9B | c.817C>T p.Q273* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV58070677; called by muse, mutect2, varscan2
- KCTD3 | c.2216A>G p.K739R | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV99379788; called by muse, mutect2
- KIAA1958 | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100516528; called by muse, mutect2, varscan2
- KLHL6 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100385089; called by muse, mutect2
- KPNA5 | c.1151C>G p.P384R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV100706452, COSV62653567; called by muse, mutect2, varscan2
- KRTAP19-2 | c.67G>T p.G23* | Nonsense Mutation (SNP) | VAF 31/174 reads (18%) | catalogued as COSV100477661; called by muse, mutect2, varscan2
- LRRK1 | c.465G>C p.W155C | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV99443536; called by muse, mutect2, varscan2
- LTBP2 | c.3121G>A p.E1041K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.559); catalogued as COSV100001035; called by muse, mutect2, varscan2
- MARCHF7 | c.21G>C p.R7S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99374183; called by muse, mutect2, varscan2
- MCTS1 | c.221G>A p.R74K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.196); catalogued as COSV100989191; called by muse, mutect2, varscan2
- MMP16 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 102/223 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV99685647, COSV99690667; called by muse, mutect2, varscan2
- MTR | c.3218C>G p.S1073C | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV100855587; called by muse, mutect2
- MYO1B | c.3082G>C p.E1028Q (on ENST00000304164; = p.E970Q on NM_012223.5) | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.266); catalogued as COSV100270208; called by muse, mutect2, varscan2
- NCAPD2 | c.3101C>T p.S1034F | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV100217483; called by muse, mutect2, varscan2
- NFE2L2 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs768430025, COSV101229451; called by muse, mutect2, varscan2
- NUMA1 | c.2308C>T p.R770* | Nonsense Mutation (SNP) | VAF 28/91 reads (31%) | catalogued as COSV61193197; called by muse, mutect2, varscan2
- OR5B17 | c.300C>G p.F100L | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); catalogued as COSV100641870, COSV100641967; called by muse, mutect2, varscan2
- PCDHA12 | c.586C>A p.L196I | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV100255240; called by muse, mutect2, varscan2
- PDGFRL | c.717G>C p.E239D | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99286721; called by muse, mutect2
- PIAS3 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100992781, COSV65171255; called by muse, mutect2, varscan2
- PLA2G12B | c.354T>G p.C118W | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100888040; called by muse, mutect2, varscan2
- RGS9 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99288142; called by muse, mutect2, varscan2
- RIC8B | c.1027C>T p.H343Y | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV100822742; called by muse, mutect2, varscan2
- RNF43 | c.766C>G p.R256G | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV101348566; called by muse, mutect2, varscan2
- RRP1 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.636); catalogued as rs750460535, COSV101513893; called by muse, mutect2, varscan2
- RTN1 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99957023; called by muse, mutect2
- SI | c.4979A>G p.H1660R | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as rs113739230, COSV100017367; called by muse, mutect2, varscan2
- SIGLEC1 | c.3946C>T p.R1316W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs563135029, COSV99171418; called by muse, mutect2
- SLC44A2 | c.760C>T p.R254C | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1355261894, COSV59836055, COSV59838669; called by muse, mutect2
- STAT5B | c.107A>C p.Q36P | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.046); catalogued as COSV99511377; called by muse, mutect2, varscan2
- TBX18 | c.1376G>C p.G459A | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV100858598; called by muse, mutect2, varscan2
- TENM3 | c.4618G>T p.D1540Y | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101305501, COSV69313088; called by muse, mutect2, varscan2
- TMPRSS9 | c.1304T>G p.F435C (on ENST00000648592; = p.F401C on NM_182973.2) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100211774; called by muse, mutect2, varscan2
- TSC2 | c.1760A>G p.Y587C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1487642536, COSV99555525; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.25530C>T p.L8510= (on ENST00000591111; = p.L7583= on NM_133378.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 15/128 reads (12%) | catalogued as rs749525418, COSV100632797; ClinVar: likely benign; called by muse, mutect2, varscan2
- VLDLR | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs769188234, COSV101173248; called by muse, mutect2, varscan2
- ZNF33B | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1463222465, COSV63942527, COSV63943211; called by muse, mutect2, varscan2
- PCDHB9 | c.2122T>A p.F708I | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- TBC1D21 | c.78del p.I27Lfs*36 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.1372-1G>A p.X458_splice | Splice Site (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- WASHC2C | c.3856G>T p.E1286* (on ENST00000336378; = p.E1265* on NM_015262.3 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- ZNF74 | c.345del p.E115Dfs*4 | Frame Shift Del (DEL) | VAF 43/153 reads (28%) | called by mutect2, pindel, varscan2
- ABLIM2 | c.429C>T p.S143= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs373865023; called by muse, mutect2, varscan2
- ALDH3B1 | c.864G>A p.Q288= | Silent (SNP) | VAF 18/155 reads (12%) | catalogued as COSV99142107; called by muse, varscan2
- ASPM | c.2430G>A p.Q810= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99661202; called by mutect2, varscan2
- C17orf58 | c.36C>T p.F12= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV57817241; called by muse, mutect2, varscan2
- DDIAS | c.630A>G p.S210= | Silent (SNP) | VAF 58/145 reads (40%) | catalogued as rs140996530; called by muse, mutect2, varscan2
- DNAH9 | c.10827G>A p.Q3609= | Silent (SNP) | VAF 52/99 reads (53%) | catalogued as COSV99308460; called by muse, mutect2
- E2F2 | c.507C>T p.I169= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100674878; called by muse, mutect2, varscan2
- ENC1 | c.834G>A p.Q278= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV100188271; called by muse, mutect2, varscan2
- FFAR1 | c.399C>T p.L133= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs773653229, COSV99323827; called by muse, mutect2, varscan2
- FRMD7 | c.1773G>A p.Q591= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as COSV100049045; called by muse, mutect2
- H3C2 | c.108G>A p.V36= | Silent (SNP) | VAF 54/181 reads (30%) | catalogued as rs759554988, COSV99451433; called by muse, mutect2, varscan2
- H3C3 | c.180G>A p.E60= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as rs1359361948, COSV100778321; called by muse, mutect2, varscan2
- IGFBP4 | c.564A>G p.S188= | Silent (SNP) | VAF 41/141 reads (29%) | catalogued as COSV99511300; called by muse, mutect2, varscan2
- KCTD8 | c.1029T>C p.D343= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100760176; called by muse, mutect2, varscan2
- KRT71 | c.171C>A p.L57= | Silent (SNP) | VAF 50/181 reads (28%) | catalogued as COSV99922424; called by muse, mutect2, varscan2
- LGALS3BP | c.1395A>G p.Q465= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV99431963; called by muse, mutect2, varscan2
- NAGPA | c.450G>A p.G150= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV100393108; called by muse, mutect2, varscan2
- NCAPD2 | c.2574C>A p.V858= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as COSV100217481, COSV59698201; called by muse, mutect2, varscan2
- NCAPD2 | c.3175C>T p.L1059= | Silent (SNP) | VAF 74/274 reads (27%) | catalogued as COSV100217486; called by muse, mutect2, varscan2
- NLRC5 | c.2280G>C p.L760= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99348373; called by muse, mutect2, varscan2
- NPHS1 | c.3255C>A p.L1085= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- NRROS | c.915C>T p.L305= | Silent (SNP) | VAF 46/112 reads (41%) | catalogued as COSV100145652; called by muse, mutect2, varscan2
- NWD1 | c.1917A>G p.G639= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV100343850; called by muse, mutect2, varscan2
- OR4D5 | c.279C>T p.S93= | Silent (SNP) | VAF 46/123 reads (37%) | catalogued as COSV100190219; called by muse, mutect2, varscan2
- PCNX2 | c.1251G>T p.A417= | Silent (SNP) | VAF 83/152 reads (55%) | catalogued as rs536208111, COSV50806313, COSV99269737; called by muse, mutect2, varscan2
- RNF19B | c.2190C>G p.A730= | Silent (SNP) | VAF 13/162 reads (8%) | catalogued as COSV99331820; called by muse, mutect2
- RSAD2 | c.153G>T p.L51= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- RSPO4 | c.243C>T p.R81= | Silent (SNP) | VAF 45/88 reads (51%) | catalogued as rs756916549, COSV54080461; called by muse, mutect2, varscan2
- RTL3 | c.1144C>T p.L382= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as rs200904872, COSV100330144; called by mutect2, varscan2
- SLC26A3 | c.1038C>T p.I346= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as rs373747349, COSV60640458; called by muse, mutect2, varscan2
- SLIT1 | c.3759C>T p.A1253= | Silent (SNP) | VAF 59/211 reads (28%) | catalogued as rs1564651444, COSV56589597; called by muse, mutect2, varscan2
- TMEM94 | c.1374C>T p.F458= | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as COSV100051014; called by muse, mutect2, varscan2
- TMEM94 | c.1957C>T p.L653= | Silent (SNP) | VAF 28/121 reads (23%) | catalogued as COSV100051016; called by muse, mutect2, varscan2
- ZFHX3 | c.4965G>C p.V1655= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV51725891, COSV99215003; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505332 C>A | 5'Flank (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- ASPH | c.323-11921C>G | Intron (SNP) | VAF 6/25 reads (24%) | catalogued as COSV100727834; called by muse, mutect2, varscan2
- C8orf86 | n.835C>T | RNA (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- CDKL1 | n.149C>T | RNA (SNP) | VAF 7/141 reads (5%) | called by muse, mutect2
- DCHS2 | n.8702C>T | RNA (SNP) | VAF 23/76 reads (30%) | catalogued as COSV61767408; called by muse, mutect2, varscan2
- RUFY3 | chr4:70794849 C>T | 3'Flank (SNP) | VAF 23/108 reads (21%) | catalogued as rs1237973726, COSV99888093; called by muse, mutect2, varscan2
- ZNF767P | n.466A>G | RNA (SNP) | VAF 44/145 reads (30%) | called by muse, mutect2, varscan2
